Somatic mutation profile of tumor specimen TCGA-2G-AAF6-01A (aliquot TCGA-2G-AAF6-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAF6, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 28.1 years (10,281 days).
Specimen TCGA-2G-AAF6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42ed029a-1aa1-4173-b708-fdd2691749eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAF6-10A (Blood Derived Normal), aliquot TCGA-2G-AAF6-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3320ded-a56f-4853-a795-2295a222fdfd

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Frame Shift Del 2, In Frame Del 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 41/232 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- COPA | c.2652_2654del p.E884del | In Frame Del (DEL) | VAF 44/209 reads (21%) | catalogued as rs778904236; called by pindel, varscan2
- ANKLE1 | c.1729A>C p.I577L (on ENST00000394458; = p.I523L on NM_152363.6) | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- ATG2B | c.4525G>T p.V1509F | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- CADM2 | c.871A>G p.N291D (on ENST00000407528 / NM_001167674.2; = p.N293D on NM_153184.4) | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CASD1 | c.1103T>G p.L368* | Nonsense Mutation (SNP) | VAF 40/167 reads (24%) | called by muse, mutect2, varscan2
- DHFR2 | c.356G>C p.S119T | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- EPHB4 | c.245del p.G82Afs*78 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | called by mutect2, pindel
- ERMARD | c.652C>A p.L218M | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GABPB1 | c.860C>G p.S287C | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PCDH15 | c.4468A>G p.I1490V | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PKHD1L1 | c.9798A>T p.E3266D | Missense Mutation (SNP) | VAF 44/269 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLXNB2 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- RAD21 | c.1635_1636del p.G547Rfs*26 | Frame Shift Del (DEL) | VAF 27/151 reads (18%) | called by mutect2, pindel, varscan2
- ZBTB9 | c.1243A>G p.I415V | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C7orf26 | c.483G>T p.P161= | Silent (SNP) | VAF 19/117 reads (16%) | catalogued as rs1382916218; called by muse, mutect2, varscan2
- GPC5 | c.846G>A p.L282= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs1423615200; called by muse, mutect2, varscan2
- MROH2B | c.3345G>A p.G1115= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs549275471, COSV68182646; called by muse, mutect2, varscan2
- ANAPC1P4 | n.1891G>A | RNA (SNP) | VAF 8/46 reads (17%) | called by mutect2, varscan2
